CCG case CUPP-B6BS — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb868333-631e-4b87-8595-7158ca6ddc13

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Year of birth: 1946; Vital status: Dead; Days to death: 538 days (1.5 years); Year of death: 2002.

Diagnoses (2)
1. Adenocarcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8140/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 54.3 years (19,846 days); Year of diagnosis: 2001; Method of diagnosis: Biopsy; AJCC staging edition: 5th; AJCC clinical T: TX; AJCC clinical N: N1; AJCC clinical M: MX; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
2. Progression of the brain (histology not recorded by GDC). Age at diagnosis: 55.2 years (20,154 days); Year of diagnosis: 2002; Days to diagnosis: 308 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (2 entries)
- Day 308 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 308 days.
- Days to follow up: 538 days (1.5 years); Disease response: With Tumor.

Exposures
- Tobacco smoking status: Smoker at Diagnosis.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Uterine Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Ovarian Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B6BS-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B6BS-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 80; Percent normal cells: 7; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
